Surgical pathology report (de-identified scan), TCGA case TCGA-G3-A5SJ, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Alberta Health Services, specimen TCGA-G3-A5SJ-01A (Primary Tumor).

[page 1 of 3]
Note: If you do not see "END OF PRINTED REPORT" at the bottom of the last page of the report **YOU DO NOT HAVE THE ENTIRE REPORT**. Please try printing it again.

CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected

Time Reported

Order Number

Status

Final

Ordering Provider

Relevant
Information

Location

Report Patient
Demographics
(for verification
purposes)

Name:

Date of Birth:

Sex: M

ICD-3

Carcinoma, hepatocellular
8/70/3

Site: Liver, hepatic NOS
C22.0

GW 4/2/13

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist

Specimen Description

A: Gallbladder

B: Liver tumor

Clinical Information

Liver lesion, hepatitis C

Diagnosis

A: Gallbladder, Cholecystectomy:

- Mild chronic cholecystitis
- Negative for atypia or malignancy

B: Liver Tumor, Local Resection:

- Hepatocellular carcinoma, moderately differentiated
- Surrounding liver parenchyma with chronic hepatitis consistent with HCV hepatitis with grade I, stage 3 change

Reported by

Electronically signed by

[page 2 of 3]
Synoptic Report

B: Liver, Resection, Macroscopic

Specimen:

Liver

Gallbladder

PROCEDURE:

Partial hepatectomy

*Minor hepatectomy (less than 3 segments)

TUMOR SIZE:

Greatest dimension: 2.3 cm

*Additional dimensions: 2.2 x 1.5 cm

TUMOR FOCALITY:

Solitary (specify location): location not given

B: Liver, Resection, Microscopic

HISTOLOGIC TYPE:

Hepatocellular carcinoma

HISTOLOGIC GRADE:

GII: Moderately differentiated

TUMOR EXTENSION (select all that apply):

Tumor confined to liver

PRIMARY TUMOR (pT):

pT1: Solitary tumor with no vascular invasion

REGIONAL LYMPH NODES (pN):

pNX: Cannot be assessed

DISTANT METASTASIS (pM):

pMX: Cannot be assessed

MARGINS:

Parenchymal margin uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 13 mm

*VENOUS (LARGE VESSEL) INVASION (V):

*Absent

*ADDITIONAL PATHOLOGIC FINDINGS:

*Hepatitis (specify type): HCV chronic hepatitis

Gross Description

Received are specimens A and B. All requisitions and specimen containers are labelled with the patient's name, The cassettes and AP identifiers are labelled with the Surgical Number

A: An intact gallbladder measuring 8.8 x 3.2 x 2.7 cm. The serosal surface is slightly roughened. The lumen contains green bile and no calculi, and the cystic duct is patent. The mucosa is velvety, and the wall averages 0.2 cm in thickness. The cystic duct lymph node is not identified. Representative sections are submitted in one block.

B: The specimen is received fresh and is subsequently placed into formalin and consists of a segmental resection of liver measuring 7.3 x 3.6 x 3.3 cm. The capsular surface of the specimen is relatively smooth except for a focal raised grey tan oval area measuring 2.0 x 1.7 cm. The margins are dyed with blue ink. The specimen is serially sectioned to reveal a well circumscribed grey tan ovoid mass measuring 2.3 x 2.2 x 1.5 cm and grossly corresponds with the capsular lesion and comes to within 1.5 cm of the blue inked resection margin.

B1-3. representative sections of tumor and gross involvement to capsular surface

B4. representative section of tumor and grossly closest point of invasion to blue inked

resection margin

No other lesions are grossly identified.

[page 3 of 3]
Microscopic Description

Sections show a relatively circumscribed, but lobulated unencapsulated hepatocellular carcinoma in a subcapsular location. The surrounding parenchyma shows active chronic inflammation with lymphoid follicle formation within portal tracts. Portal tracts are expanded and portal-portal fibrous bands are formed, without complete nodule formation. Focal areas show active interface hepatitis in an occasional portal tract. Lobular

inflammation is minimal. There is mild macrovesicular steatosis. No other abnormal inclusions are present.

The hepatocellular carcinoma shows areas with well differentiated morphology, but there are also areas with significant nuclear pleomorphism and mitotic activity. The cells are arranged predominantly in sheets, but patchy areas show gland-like profiles of rosette formation, as well as trabecular architecture. Immunostains show patchy HepPar1 staining, but distinct and well developed canalicular pattern on CD10. CEA also shows focal canalicular pattern, while CK19 shows patchy staining. Focal PAS positivity in microglandular lumina is seen. No clear evidence of vascular invasion can be identified.

Accession
Number

Encounter
Number

Patient Location

- END OF PRINTED REPORT -

TPA Discrepancy		
Pathology Discrepancy		

Source: NCI Genomic Data Commons file 00f73a96-c160-4df2-8c6a-6573eeabd3ae (TCGA-G3-A5SJ.5237C744-2C11-4340-BC70-9AD10238F1E6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).